Somatic mutation profile of tumor specimen ALCH-B4EC-TTP1-A (aliquot ALCH-B4EC-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4EC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 45.3 years (16,564 days).
Specimen ALCH-B4EC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60a6fc92-3d62-44c5-977b-bd69076333ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4EC-NB1-A (Blood Derived Normal), aliquot ALCH-B4EC-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b3e8a08-03de-4344-af88-164c1b1dc1d0

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, RNA 2, Silent 2, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-1G>T p.X261_splice | Splice Site (SNP) | VAF 58/289 reads (20%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATF7IP2 | c.1604A>G p.E535G | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs762493285; called by muse, mutect2, varscan2
- FREM3 | c.116A>T p.E39V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV61680876; called by muse, mutect2
- PKMYT1 | c.1155C>T p.A385= | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as rs1325249340, COSV51892147; called by muse, mutect2, varscan2
- TRIOBP | c.4187C>T p.P1396L | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as CM154694, COSV60377191; called by muse, mutect2, varscan2
- ARHGAP35 | c.1897T>A p.Y633N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GABRG3 | c.429G>T p.W143C | Missense Mutation (SNP) | VAF 69/379 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HRH2 | c.153C>A p.N51K | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MKLN1 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MON2 | c.1156T>G p.F386V | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- NTRK2 | c.2224G>C p.V742L (on ENST00000323115 / NM_001369534.1; = p.V758L on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ROBO2 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RTN4 | c.2278_2280del p.Q760del | In Frame Del (DEL) | VAF 25/160 reads (16%) | called by mutect2, pindel, varscan2
- TRIM7 | c.902C>A p.T301N | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2
- ZNF592 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZP4 | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- EIF2D | c.1332A>G p.L444= | Silent (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2, varscan2
- ZFHX2 | c.948G>A p.A316= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs777886928; called by muse, mutect2, varscan2
- C1orf229 | n.695C>T | RNA (SNP) | VAF 5/19 reads (26%) | catalogued as rs1323797891; called by muse, mutect2, varscan2
- MDS2 | n.955G>A | RNA (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
